Somatic mutation profile of tumor specimen TARGET-30-PAUBFU-01A (aliquot TARGET-30-PAUBFU-01A-01D) from TARGET case TARGET-30-PAUBFU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 4.2 years (1,520 days).
Specimen TARGET-30-PAUBFU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d930d37-861b-4d6f-8716-cdda942900ff.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUBFU-10A (Blood Derived Normal), aliquot TARGET-30-PAUBFU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2a7801f-8b7c-4512-860f-b169ebf0b97a

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PGM3 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285899855; called by muse, mutect2
- VEGFC | c.1239G>C p.W413C | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FHDC1 | c.3249C>T p.S1083= | Silent (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
